Somatic mutation profile of tumor specimen MP2PRT-PAVJUN-TBP1-A (aliquot MP2PRT-PAVJUN-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVJUN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,534 days).
Specimen MP2PRT-PAVJUN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf717a8f-2d08-4696-b29a-e784a810cbe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJUN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJUN-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28f175b2-2500-40fb-9014-3e70381bbedf

The open-access MAF lists 11 somatic variants for this specimen: 11 protein-altering or splice-affecting.
By variant classification: Missense Mutation 9, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 49/368 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 22/188 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALX1 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs778396653; called by muse, mutect2
- CACNA1B | c.3543C>T p.N1181= | Splice Region (SNP) | VAF 31/268 reads (12%) | catalogued as rs1358025316, COSV99500736; called by muse, mutect2, varscan2
- CCDC40 | c.2605G>A p.V869M | Missense Mutation (SNP) | VAF 42/293 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs749295941, COSV66477838; called by muse, mutect2, varscan2
- DLL4 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 73/511 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.963); catalogued as rs201505624; called by muse, mutect2, varscan2
- NOTCH2 | c.5152C>T p.R1718C | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1233590749, COSV56691983; called by muse, mutect2
- ZNF581 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 47/563 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.973); catalogued as rs1480178022; called by muse, mutect2
- IGHD2-8 | c.30_31delinsTTGGT | In Frame Ins (INS) | VAF 23/156 reads (15%) | called by pindel, varscan2*
- SHANK1 | c.3198C>G p.H1066Q | Missense Mutation (SNP) | VAF 73/588 reads (12%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, varscan2
- TMEM50B | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 43/403 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
